Gene-level copy-number profile of specimen HCM-CSHL-0653-C18-85O from HCMI case HCM-CSHL-0653-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.9 years (20,789 days).
Specimen HCM-CSHL-0653-C18-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ae500b81-e24b-4377-ba5b-26d428e2db8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0653-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/fdeffd98-895a-4728-99ea-280a97aaddb0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 33; copy number 2: 13,550; copy number 3: 20,194; copy number 4: 21,858; copy number 5: 101; copy number 6: 1,038; copy number 7: 46; copy number 8: 1,541; copy number 9: 35.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,622 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:94,896,949–94,927,223, 1 gene, copy number 7: CNN3.
- chr1:95,310,928–95,318,263, 1 gene, copy number 7: LINC01760.
- chr13:18,609,132–62,029,572, 757 genes, copy number 8 (broad region; genes not listed).
- chr13:63,667,681–63,844,125, 8 genes, copy number 8: LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, OR7E104P, AL445238.1.
- chr13:63,975,451–83,298,167, 169 genes, copy number 8 (broad region; genes not listed).
- chr13:84,020,327–114,337,626, 380 genes, copy number 8 (broad region; genes not listed).
- chr20:25,919,499–25,919,681, 1 gene, copy number 7: CFTRP1.
- chr20:26,135,983–26,251,546, 4 genes, copy number 7: AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr20:31,465,506–39,224,748, 264 genes, copy number 7–9 (broad region; genes not listed).
- chr20:45,534,196–45,579,326, 8 genes, copy number 7: WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2.
- chr20:46,008,908–46,100,176, 5 genes, copy number 7: MMP9, SLC12A5-AS1, SLC12A5, NCOA5, RPL13P2.
- chr20:50,794,894–50,882,676, 2 genes, copy number 7 (within-gene range 6–7): BCAS4, TMSB4XP6.
- chr20:54,208,087–54,269,542, 2 genes, copy number 7: PFDN4, AL133335.1.
- chr20:54,859,688–54,859,812, 1 gene, copy number 7: RNU4ATAC7P.
- chr22:18,951,934–18,959,512, 1 gene, copy number 8: AC007326.2.
- chr22:19,121,529–19,447,450, 14 genes, copy number 7 (within-gene range 6–7): AC004471.1, AC004471.2, TSSK1A, ESS2, TSSK2, GSC2, LINC01311, SLC25A1, CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62, HIRA.
- chr22:19,365,766–19,366,044, 1 gene, copy number 7 (within-gene range 6–7): RN7SL168P.
- chr22:19,523,024–19,527,545, 1 gene, copy number 7: CLDN5.
- chr22:30,922,308–30,968,774, 2 genes, copy number 7: MORC2-AS1, MORC2.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
